Gene-level copy-number profile of tumor specimen TCGA-24-2033-01A from TCGA case TCGA-24-2033, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 87.5 years (31,977 days).
Specimen TCGA-24-2033-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.eeb3061c-910c-407b-a949-a65bf1b74689.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-2033-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bfba66c5-7e04-4937-9bf0-092b2f3e7298

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,132; copy number 2: 10,826; copy number 3: 27,490; copy number 4: 16,295; copy number 5: 2,026; copy number 6: 573; copy number 7: 1,345; copy number 8: 22; copy number 12: 34; copy number 16: 71.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-2033-01A-01D-0663-01): tumor purity 0.82, ploidy 3.32, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,472 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:97,358,265–137,425,021, 542 genes, copy number 7–8 (broad region; genes not listed).
- chr11:77,514,936–78,444,049, 33 genes, copy number 7: CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728.
- chr11:117,986,370–118,925,608, 46 genes, copy number 7: IL10RA, SMIM35, RN7SL828P, TMPRSS4, SCN4B, SCN2B, JAML, HSPE1P18, MPZL3, MPZL2, AP002800.1, CD3E, AP001582.1, CD3D, CD3G, UBE4A, AP001267.1, AP001267.5, ATP5MG, AP001267.4, AP001267.2, KMT2A, AP001267.3, TTC36, TMEM25, IFT46, RPL5P30, ARCN1, RNU6-1157P, PHLDB1, AP000941.1, MIR6716, TREH, TREHP1, AP002954.1, RNU6-376P, AP002954.2, DDX6, AP004609.3, AP004609.2, SETP16, Y_RNA, CXCR5, AP004609.1, BCL9L, MIR4492.
- chr12:24,566,964–25,108,334, 15 genes, copy number 7: LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2.
- chr19:12,965,159–22,010,949, 457 genes, copy number 7–16 (within-gene range 4–16) (broad region; genes not listed).
- chr20:48,624,252–64,313,132, 379 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 223. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
